Somatic mutation profile of tumor specimen TCGA-56-7579-01A (aliquot TCGA-56-7579-01A-11D-2042-08) from TCGA case TCGA-56-7579, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 62.0 years (22,632 days).
Specimen TCGA-56-7579-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d33aa00-9dff-4566-aee2-69a4081d7ab3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7579-10A (Blood Derived Normal), aliquot TCGA-56-7579-10A-01D-2042-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d5ca136-25a3-4233-a61d-9c85e98ca97d

The open-access MAF lists 282 somatic variants for this specimen: 207 protein-altering or splice-affecting, 67 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 175, Silent 67, Nonsense Mutation 16, Splice Site 7, Frame Shift Del 6, Intron 3, 3'UTR 2, Frame Shift Ins 2, Splice Region 1, 5'Flank 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.14579G>A p.G4860E | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343617695, COSV101291398; called by mutect2, varscan2
- ABCB10 | c.1840G>T p.A614S | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV100748039; called by muse, mutect2, varscan2
- ABCC9 | c.3227T>A p.I1076K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1356591712, COSV99684907; called by muse, mutect2, varscan2
- ABLIM1 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99522488; called by muse, mutect2, varscan2
- AC011448.1 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99389204; called by muse, mutect2, varscan2
- ADAMTS12 | c.3763C>T p.H1255Y | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as rs922399712, COSV100711466, COSV61255312; called by muse, mutect2, varscan2
- ADAMTS7 | c.4216G>T p.D1406Y | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV101183200; called by muse, mutect2, varscan2
- ADGRB1 | c.3378G>T p.K1126N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs369637081; called by muse, varscan2
- AGRN | c.3178T>A p.S1060T | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV101038978; called by muse, mutect2
- ALOX15 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs200554414, COSV99541619; called by muse, mutect2, varscan2
- ANK2 | c.2288C>A p.T763K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100003186; called by muse, mutect2
- ANKRD27 | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1404280087, COSV100043035; called by muse, mutect2, varscan2
- ANTKMT | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99557530; called by muse, mutect2, varscan2
- ASXL3 | c.6586C>G p.P2196A | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as rs752151003, COSV99323122, COSV99325899; called by muse, mutect2, varscan2
- B4GALT1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101123003; called by muse, mutect2, varscan2
- BPTF | c.7628C>T p.S2543F | Missense Mutation (SNP) | VAF 62/80 reads (78%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.365); catalogued as rs1568143530, COSV100075620; called by muse, varscan2
- BPTF | c.7687C>G p.Q2563E | Missense Mutation (SNP) | VAF 52/74 reads (70%) | SIFT tolerated (0.58); PolyPhen benign (0.107); catalogued as COSV100075624; called by muse, varscan2
- BRINP2 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV100838226, COSV64175956; called by muse, mutect2, varscan2
- C19orf18 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.638); catalogued as COSV100071923; called by muse, mutect2, varscan2
- C3 | c.4543G>C p.E1515Q | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99837070; called by muse, mutect2, varscan2
- CACNA2D4 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | catalogued as rs1341380324, COSV54950626, COSV99766187; called by muse, mutect2, varscan2
- CCDC39 | c.1706A>C p.K569T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs961031844, COSV56490462, COSV99870161; called by muse, mutect2, varscan2
- CD93 | c.989G>T p.C330F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99849429; called by muse, mutect2, varscan2
- CD96 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as COSV99343311; called by muse, mutect2, varscan2
- CDH18 | c.812-1G>C p.X271_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | catalogued as COSV56954316, COSV99937153; called by muse, mutect2, varscan2
- CDK13 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 42/206 reads (20%) | catalogued as COSV99475893; called by muse, mutect2, varscan2
- CIB4 | c.525G>T p.M175I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV56599866; called by muse, mutect2, varscan2
- CKAP5 | c.1607C>A p.S536Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV100371170; called by muse, mutect2, varscan2
- CLEC14A | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs780176144, COSV100643636, COSV60563438; called by muse, mutect2, varscan2
- CLGN | c.1405C>T p.H469Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100346754; called by muse, mutect2, varscan2
- CNGA3 | c.1559A>G p.Y520C | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99737202; called by muse, mutect2, varscan2
- COL19A1 | c.1994G>A p.G665E | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100507034; called by muse, mutect2, varscan2
- COL27A1 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 61/97 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100621193; called by muse, mutect2, varscan2
- COL3A1 | c.4172A>G p.K1391R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs373015577; called by muse, mutect2, varscan2
- COL9A2 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV101025747; called by muse, mutect2, varscan2
- CSMD1 | c.9500T>A p.L3167H (on ENST00000520002; = p.L3166H on NM_033225.6) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.621); catalogued as COSV100151806; called by muse, mutect2, varscan2
- CTTNBP2 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 43/97 reads (44%) | catalogued as COSV99354530; called by muse, mutect2, varscan2
- CUBN | c.8967C>A p.S2989R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs560485793, COSV64714996; called by muse, mutect2, varscan2
- CYP11B2 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1477704273, COSV100011268; called by muse, mutect2, varscan2
- DDX58 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV101153111; called by muse, mutect2, varscan2
- DLC1 | c.911A>G p.N304S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.321); catalogued as rs748657688, COSV52327963, COSV99364612; called by muse, mutect2, varscan2
- DNAH5 | c.11456T>C p.V3819A | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as rs776767138, COSV99452362; called by muse, mutect2
- DOCK4 | c.1175C>G p.S392* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV101455654; called by muse, mutect2, varscan2
- DPP9 | c.2309A>G p.Y770C (on ENST00000598800; = p.Y799C on NM_139159.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99506360; called by muse, mutect2, varscan2
- DPYSL2 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.348); catalogued as COSV100234051; called by muse, mutect2, varscan2
- DRC1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV99985600; called by muse, mutect2, varscan2
- ECE2 | c.1286+2T>A p.X429_splice (on ENST00000357474 / NM_001100120.2; = p.X354_splice on NM_001037324.3) | Splice Site (SNP) | VAF 33/279 reads (12%) | catalogued as COSV100668765; called by muse, mutect2, varscan2
- EMILIN3 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100182719; called by muse, mutect2, varscan2
- EPHA2 | c.2114G>T p.R705L | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV100626236, COSV100626377; called by muse, mutect2, varscan2
- ESRRB | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99835591; called by muse, mutect2, varscan2
- EXOC3L2 | c.2006A>T p.Q669L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.561); catalogued as COSV99374602; called by muse, mutect2, varscan2
- EXTL1 | c.33G>C p.W11C | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.751); catalogued as COSV100959123; called by muse, mutect2, varscan2
- F2RL1 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99688854; called by muse, mutect2, varscan2
- FILIP1L | c.3046C>T p.Q1016* (on ENST00000354552 / NM_182909.3; = p.Q776* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/90 reads (42%) | catalogued as COSV100497202; called by muse, mutect2, varscan2
- FMN2 | c.2296C>G p.R766G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100146631; called by muse, mutect2, varscan2
- FRAS1 | c.5294C>G p.S1765* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99354555, COSV99356662; called by muse, mutect2, varscan2
- FSIP1 | c.1522C>A p.Q508K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV100618281; called by muse, mutect2, varscan2
- GABRA1 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV99196153; called by muse, mutect2, varscan2
- GALNT13 | c.1396-1G>T p.X466_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV67242986; called by muse, mutect2, varscan2
- GAPDHS | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV55884150, COSV99722854; called by muse, mutect2, varscan2
- GDA | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99429584; called by muse, mutect2, varscan2
- GDF11 | c.1217G>A p.C406Y | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99144045; called by muse, mutect2, varscan2
- GLP2R | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs768614899, COSV99302312; called by muse, mutect2, varscan2
- GPM6A | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs116256200, COSV54537181; called by muse, mutect2, varscan2
- GRID2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as COSV99944477; called by muse, mutect2, varscan2
- GUCY1A2 | c.1963C>A p.R655S | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV56478103, COSV99976054; called by muse, mutect2, varscan2
- GYPA | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV99302122; called by muse, mutect2, varscan2
- H2BC4 | c.123C>A p.Y41* | Nonsense Mutation (SNP) | VAF 78/153 reads (51%) | catalogued as COSV100019881, COSV100020016; called by muse, mutect2, varscan2
- HCLS1 | c.395A>T p.D132V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100100974; called by muse, mutect2, varscan2
- HDGF | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 66/185 reads (36%) | catalogued as COSV100625856; called by muse, mutect2, varscan2
- HGF | c.483C>T p.S161= | Splice Region (SNP) | VAF 13/62 reads (21%) | catalogued as rs762973783, COSV99737954; called by muse, mutect2, varscan2
- HIPK2 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100702421; called by muse, mutect2, varscan2
- HPSE2 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 66/253 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.873); catalogued as COSV100986056; called by muse, mutect2, varscan2
- IGHV6-1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs1434348475; called by muse, mutect2, varscan2
- ITGA2 | c.2162A>G p.N721S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs570102567, COSV99671271; called by muse, varscan2
- KCNB2 | c.1770G>T p.Q590H | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV101578896; called by muse, mutect2, varscan2
- KCNN3 | c.1432G>C p.V478L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.208); catalogued as COSV99678926; called by muse, mutect2, varscan2
- KIF14 | c.4868A>C p.K1623T | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100950993, COSV66264555; called by muse, mutect2, varscan2
- KMT5B | c.2063G>T p.S688I | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV100430374; called by muse, mutect2, varscan2
- KNDC1 | c.4588C>G p.Q1530E | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100465782; called by muse, mutect2, varscan2
- LARP4 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.418); catalogued as COSV99529491; called by muse, mutect2, varscan2
- LPGAT1 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV100878187; called by muse, mutect2, varscan2
- LRBA | c.1426C>A p.L476I | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100841953; called by muse, mutect2, varscan2
- LRIT2 | c.1058C>G p.P353R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as COSV100259246; called by muse, mutect2, varscan2
- LRP2 | c.8465G>C p.C2822S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99789672; called by muse, mutect2, varscan2
- LRP6 | c.2131G>A p.A711T | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs768076655, COSV99744075; called by muse, mutect2, varscan2
- LRP6 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.775); catalogued as COSV99744077; called by muse, mutect2, varscan2
- LRRC40 | c.619A>T p.N207Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100918821; called by muse, mutect2
- LRRC7 | c.577G>A p.A193T (on ENST00000651989 / NM_001370785.2; = p.A160T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV99228649; called by muse, mutect2, varscan2
- LVRN | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.346); catalogued as COSV100773599; called by muse, mutect2, varscan2
- MAGEB2 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 21/34 reads (62%) | catalogued as rs931571153, COSV100975724, COSV66781466; called by muse, mutect2, varscan2
- MAGEE2 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs772879834, COSV64898077; called by muse, mutect2, varscan2
- MAP6 | c.1158G>T p.K386N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100496836, COSV59077034; called by muse, mutect2, varscan2
- MARK2 | c.1500G>T p.Q500H (on ENST00000402010 / NM_001039469.2; = p.Q499H on NM_004954.5) | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV100158952; called by muse, mutect2, varscan2
- MEFV | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99561138; called by muse, mutect2, varscan2
- METTL4 | c.829+1G>C p.X277_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as rs148311311, COSV100170692; called by muse, mutect2, varscan2
- MLPH | c.1341C>A p.D447E | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as COSV99222492; called by muse, mutect2, varscan2
- MRTFA | c.1344C>A p.D448E | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); catalogued as COSV100844266; called by muse, mutect2, varscan2
- MYH4 | c.2228A>G p.K743R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.238); catalogued as COSV99701896; called by muse, mutect2, varscan2
- MYH8 | c.905-1G>T p.X302_splice | Splice Site (SNP) | VAF 47/114 reads (41%) | catalogued as COSV101238572, COSV101238594; called by muse, mutect2, varscan2
- MYO5C | c.3259G>T p.D1087Y | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV99955165; called by muse, mutect2, varscan2
- NAALADL2 | c.779T>A p.L260H | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV101458191; called by muse, mutect2, varscan2
- NCKAP5 | c.4372G>T p.A1458S | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.026); catalogued as COSV100493707, COSV58469898; called by muse, mutect2, varscan2
- NF1 | c.6991T>C p.Y2331H (on ENST00000358273 / NM_001042492.3; = p.Y2310H on NM_000267.3) | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100647855; called by muse, mutect2, varscan2
- NLRP14 | c.1475A>T p.Y492F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV100205274; called by mutect2, varscan2
- NR5A2 | c.716C>A p.P239H (on ENST00000367362 / NM_205860.3; = p.P193H on NM_003822.5) | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV99371470; called by muse, varscan2
- NUP54 | c.776C>G p.T259R | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV99345412; called by muse, mutect2, varscan2
- NYNRIN | c.5057C>T p.A1686V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV101230650; called by muse, mutect2, varscan2
- OR10K1 | c.65G>T p.R22M | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV56872442; called by muse, mutect2, varscan2
- OR12D2 | c.383T>G p.L128R | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101011399; called by muse, mutect2, varscan2
- OR14C36 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.387); catalogued as COSV100507606, COSV58601992; called by muse, mutect2, varscan2
- OR2A5 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 60/197 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs370941449, COSV68738884, COSV68739222; called by muse, mutect2, varscan2
- OR2J2 | c.719G>C p.R240T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV101013420; called by muse, mutect2
- OR2T33 | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100532180; called by muse, mutect2, varscan2
- OR4C11 | c.321C>A p.C107* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV100155420; called by muse, varscan2
- OR51G1 | c.709C>A p.L237I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as rs772022314, COSV100429340; called by muse, mutect2, varscan2
- OR56A4 | c.917T>C p.F306S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100417647; called by muse, mutect2, varscan2
- OR5H1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs540957735, COSV100641751, COSV100641786; called by muse, mutect2, varscan2
- OR5M8 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as rs770196855, COSV59117179; called by muse, mutect2, varscan2
- OR6C1 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101110531; called by muse, mutect2, varscan2
- OR8J3 | c.151G>T p.V51F | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs1450325315, COSV100040967; called by muse, mutect2, varscan2
- OTC | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99234290; called by muse, varscan2
- PABPC4 | c.574A>G p.N192D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100790909; called by muse, mutect2, varscan2
- PAPPA2 | c.1972G>C p.D658H | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100866961; called by muse, mutect2, varscan2
- PCDH15 | c.3865A>G p.I1289V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.562); catalogued as rs1258330774, COSV100225200; called by muse, mutect2, varscan2
- PCDH15 | c.2815G>T p.A939S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100225204; called by muse, mutect2, varscan2
- PCDHB1 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV100128317; called by muse, mutect2, varscan2
- PCDHB5 | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.075); catalogued as COSV50647142, COSV99169321; called by muse, mutect2
- PCDHGB1 | c.2135G>C p.R712P | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99543290; called by muse, mutect2, varscan2
- PCNT | c.866C>G p.A289G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100855857; called by muse, varscan2
- PDLIM3 | c.551C>T p.P184L (on ENST00000284770 / NM_001257963.1; = p.P351L on NM_014476.6) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761204525, COSV99507750; called by muse, mutect2, varscan2
- PEAK1 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV100433315; called by muse, mutect2, varscan2
- PLXNB3 | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.63); PolyPhen benign (0.138); catalogued as COSV100737715; called by muse, mutect2, varscan2
- PMPCB | c.837C>A p.F279L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99971374; called by muse, mutect2, varscan2
- PNLIP | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV100981909; called by muse, mutect2, varscan2
- POLDIP2 | c.160C>G p.R54G | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99134834, COSV99134842; called by muse, mutect2, varscan2
- POU5F2 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV101232883; called by muse, mutect2
- PPP1R9A | c.2959G>A p.E987K | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as rs1306698420, COSV56882384, COSV56909914; called by muse, mutect2, varscan2
- PSMB8 | c.344G>T p.G115V (on ENST00000374882 / NM_148919.4; = p.G111V on NM_004159.5) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100841267; called by muse, mutect2, varscan2
- PTPRO | c.173T>C p.V58A | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.031); catalogued as COSV99841317; called by muse, mutect2, varscan2
- RASGEF1A | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV100988703; called by muse, mutect2
- RELN | c.4173G>T p.E1391D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.817); catalogued as COSV100634403, COSV59005917; called by muse, mutect2, varscan2
- RNF213 | c.1513G>A p.G505R | Missense Mutation (SNP) | VAF 89/112 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV100173773; called by muse, mutect2, varscan2
- RNMT | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV100054790; called by muse, mutect2, varscan2
- RRP15 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as COSV65118237, COSV65118668; called by muse, mutect2
- RSPH6A | c.825G>C p.Q275H | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV99680028; called by muse, mutect2, varscan2
- RSRC2 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.356); catalogued as rs1372241165, COSV100063738; called by muse, mutect2, varscan2
- RTF1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs1383317474, COSV101048079; called by muse, mutect2
- RYR2 | c.11039G>T p.C3680F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV63680106; called by muse, mutect2
- SCN1A | c.4306G>T p.D1436Y (on ENST00000303395 / NM_001202435.3; = p.D1425Y on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100321350, COSV57681066; called by muse, mutect2, varscan2
- SCNN1B | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100225855; called by muse, mutect2, varscan2
- SEMA5B | c.1294G>T p.G432C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99532730; called by muse, mutect2
- SERPINA3 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.052); catalogued as COSV101261768; called by muse, mutect2, varscan2
- SERPINA4 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV100097370; called by muse, mutect2, varscan2
- SI | c.3805T>A p.F1269I | Missense Mutation (SNP) | VAF 52/349 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100016594; called by muse, mutect2, varscan2
- SIDT1 | c.535T>C p.F179L | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs767228919, COSV99334414; called by muse, mutect2, varscan2
- SIX2 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100284258; called by muse, mutect2, varscan2
- SLC12A4 | c.1544C>A p.T515K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100312038; called by muse, mutect2, varscan2
- SLC45A2 | c.1368G>T p.E456D | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99672974; called by muse, mutect2, varscan2
- SLC4A10 | c.2461G>T p.A821S (on ENST00000446997 / NM_001354461.2; = p.A791S on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99761709, COSV99765107; called by muse, mutect2, varscan2
- SLC4A4 | c.2976C>A p.Y992* (on ENST00000264485 / NM_001098484.3; = p.Y948* on NM_003759.4) | Nonsense Mutation (SNP) | VAF 16/129 reads (12%) | catalogued as COSV99140425, COSV99141092; called by muse, mutect2, varscan2
- SLC5A11 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.147); catalogued as COSV100762864; called by muse, mutect2, varscan2
- SLC8A3 | c.2350G>A p.G784S (on ENST00000381269 / NM_183002.3; = p.G782S on NM_033262.4) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99385748; called by muse, mutect2, varscan2
- SMAP2 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV101019209; called by muse, mutect2, varscan2
- SMOC2 | c.655G>C p.E219Q (on ENST00000356284 / NM_001166412.2; = p.E230Q on NM_022138.3) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100635407; called by muse, mutect2, varscan2
- SPATA31D1 | c.4356G>T p.E1452D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.558); catalogued as rs1364778987, COSV100782937, COSV100782938; called by muse, mutect2, varscan2
- SPATA31E1 | c.1898A>T p.N633I | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100350801; called by muse, mutect2, varscan2
- SYNE1 | c.11226G>T p.M3742I (on ENST00000367255 / NM_182961.4; = p.M3727I on NM_033071.3) | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1347276549, CM1410213, COSV54921440; called by muse, mutect2, varscan2
- SYNE1 | c.8038A>T p.K2680* (on ENST00000367255 / NM_182961.4; = p.K2687* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99573603; called by muse, mutect2, varscan2
- TACR1 | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV100538081; called by muse, mutect2, varscan2
- TBX3 | c.752G>T p.R251L (on ENST00000257566 / NM_016569.4; = p.R231L on NM_005996.4) | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57470179, COSV57473129, COSV99983989; called by muse, mutect2, varscan2
- TCF25 | c.1023-2A>G p.X341_splice | Splice Site (SNP) | VAF 58/110 reads (53%) | catalogued as COSV99643245; called by muse, mutect2, varscan2
- TEX11 | c.250G>A p.G84R (on ENST00000344304; = p.G69R on NM_031276.3) | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100722076; called by muse, mutect2, varscan2
- TEX15 | c.7615G>C p.D2539H (on ENST00000256246; = p.D2922H on NM_001350162.2) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.465); catalogued as COSV56353718, COSV99821854; called by muse, mutect2, varscan2
- TSHZ1 | c.616A>T p.K206* (on ENST00000580243 / NM_001308210.2; = p.K161* on NM_005786.6) | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100433860; called by muse, mutect2
- TTN | c.51632G>C p.G17211A (on ENST00000591111; = p.G9787A on NM_003319.4) | Missense Mutation (SNP) | VAF 98/254 reads (39%) | PolyPhen benign (0.027); catalogued as COSV100623144; called by muse, mutect2, varscan2
- TTN | c.8836G>C p.E2946Q (on ENST00000591111; = p.E2900Q on NM_003319.4) | Missense Mutation (SNP) | VAF 78/200 reads (39%) | PolyPhen possibly damaging (0.743); catalogued as COSV100623149; called by muse, mutect2, varscan2
- UNC5D | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 126/208 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.077); catalogued as COSV54811099, COSV99773557; called by muse, mutect2, varscan2
- UPB1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs753638837, COSV100387023; called by muse, mutect2, varscan2
- VCAM1 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99658791; called by muse, mutect2, varscan2
- VPS13C | c.10952+1G>T p.X3651_splice (on ENST00000644861 / NM_020821.3; = p.X3608_splice on NM_017684.5) | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV99829570; called by muse, mutect2, varscan2
- XCR1 | c.631A>T p.T211S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.948); catalogued as COSV100499431; called by muse, mutect2, varscan2
- YTHDF2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100863828; called by muse, mutect2, varscan2
- ZCCHC3 | c.966G>C p.E322D | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.06); catalogued as COSV101210884; called by muse, mutect2, varscan2
- ZFP42 | c.636T>A p.H212Q | Missense Mutation (SNP) | VAF 106/191 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100479079; called by muse, mutect2, varscan2
- ZNF423 | c.884C>A p.P295Q (on ENST00000563137 / NM_001379286.1; = p.P287Q on NM_015069.4) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); catalogued as COSV52184195, COSV52201454; called by muse, mutect2, varscan2
- ZNF709 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101172248; called by muse, mutect2, varscan2
- ZNF770 | c.1489C>G p.H497D | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100696020; called by muse, mutect2, varscan2
- ZNF804B | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs756343735, COSV60828534; called by muse, mutect2, varscan2
- ZNF85 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226722343, COSV100060030; called by muse, mutect2, varscan2
- ZP2 | c.840T>A p.F280L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99559692; called by muse, mutect2, varscan2
- ENPP1 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by muse, mutect2
- ERP27 | c.47_48del p.T16Mfs*2 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, pindel
- GRIN3A | c.2686_2693del p.S896Vfs*7 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- HEATR3 | c.1299del p.T435Lfs*21 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- IGKV2D-24 | c.277G>C p.G93R | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IGKV6D-21 | c.319T>A p.C107S | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPA | c.104del p.L35Wfs*54 | Frame Shift Del (DEL) | VAF 33/97 reads (34%) | called by mutect2, pindel, varscan2
- PAQR4 | c.485_488dup p.L165Cfs*71 | Frame Shift Ins (INS) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- POLR2A | c.5195C>T p.P1732L | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- SLAMF1 | c.1003_1004del p.S335Lfs*11 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | called by pindel, varscan2
- SPATA31A3 | c.2750G>C p.G917A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.084); called by mutect2, varscan2
- SPOCD1 | c.2812del p.R938Gfs*122 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- WASHC2C | c.1473C>G p.F491L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XAGE1B | c.240_241insT p.V81Cfs*16 | Frame Shift Ins (INS) | VAF 10/95 reads (11%) | called by mutect2, pindel, varscan2
- ZNF140 | c.194G>A p.W65* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- AGTR1 | c.765C>A p.P255= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs768353305, COSV100837112; called by muse, mutect2, varscan2
- CEBPD | c.730C>T p.L244= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV52388436; called by muse, mutect2, varscan2
- CEP83 | c.1302G>A p.Q434= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV60412427; called by muse, mutect2, varscan2
- CNTNAP5 | c.1356G>A p.S452= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs377134209; called by muse, mutect2, varscan2
- COL11A1 | c.153A>C p.P51= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100617731; called by muse, mutect2, varscan2
- COL22A1 | c.480C>T p.D160= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1220903304, COSV57339352, COSV57348952; called by muse, mutect2, varscan2
- CYP1A1 | c.1011C>A p.P337= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV101122361; called by muse, mutect2, varscan2
- DAB1 | c.1584A>G p.S528= (on ENST00000371231; = p.S495= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV100976490; called by muse, mutect2, varscan2
- DCHS1 | c.9438G>A p.A3146= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs781629251, COSV100197636; called by muse, varscan2
- DDX28 | c.588G>T p.L196= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV100193071; called by muse, mutect2, varscan2
- DMGDH | c.1047C>T p.I349= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV99669319; called by muse, mutect2, varscan2
- EPDR1 | c.286T>C p.L96= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV99554595; called by muse, mutect2, varscan2
- ESPL1 | c.183G>C p.L61= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99229597; called by muse, mutect2, varscan2
- FCHO1 | c.1110C>A p.A370= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as COSV53185032, COSV99406304; called by muse, mutect2, varscan2
- GABRR3 | c.891T>A p.P297= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV101512335; called by muse, mutect2, varscan2
- GIT2 | c.117G>C p.R39= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV58085912; called by muse, mutect2, varscan2
- GOLGB1 | c.792C>T p.H264= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as rs373824875; called by muse, mutect2, varscan2
- GP2 | c.912C>A p.V304= (on ENST00000381362 / NM_001007240.3; = p.V301= on NM_001502.4) | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV100221586; called by muse, mutect2, varscan2
- GPR139 | c.342C>T p.T114= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV100429972, COSV100429983; called by muse, mutect2, varscan2
- HNRNPH2 | c.150A>G p.E50= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV99516507; called by muse, mutect2, varscan2
- HPD | c.792C>G p.V264= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100000182; called by muse, mutect2, varscan2
- ITGAX | c.1908G>C p.A636= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs773833533, COSV51652155, COSV99191928; called by muse, mutect2, varscan2
- KCNB2 | c.840C>A p.T280= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV101578894; called by muse, mutect2, varscan2
- LILRA2 | c.945G>C p.L315= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99253750; called by muse, mutect2, varscan2
- LRP1 | c.8982G>A p.Q2994= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV99676683; called by muse, mutect2, varscan2
- LRRC8B | c.1164A>C p.L388= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV100446642; called by muse, mutect2, varscan2
- MAB21L4 | c.1003C>A p.R335= (on ENST00000388934 / NM_001085437.3; = p.R167= on NM_024861.4) | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV100278634, COSV56743603; called by muse, mutect2, varscan2
- NPHS2 | c.1059C>A p.P353= | Silent (SNP) | VAF 43/89 reads (48%) | catalogued as rs373172860, COSV100858195; called by muse, mutect2, varscan2
- NRXN1 | c.2589C>A p.S863= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100456273; called by muse, mutect2, varscan2
- OR2A5 | c.935G>A p.*312= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs768989084, COSV101278807; called by muse, mutect2, varscan2
- PCDHB5 | c.1164C>A p.L388= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV50652033, COSV99169323; called by muse, mutect2
- PCDHGA2 | c.1896G>A p.L632= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as COSV99543288; called by muse, mutect2, varscan2
- PEG3 | c.390A>G p.P130= | Silent (SNP) | VAF 40/79 reads (51%) | catalogued as rs764482053, COSV99689880; called by muse, mutect2, varscan2
- PKD1L2 | c.1200A>G p.Q400= | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as rs755415206, COSV100450124; called by muse, mutect2, varscan2
- PLCB1 | c.1110A>G p.A370= | Silent (SNP) | VAF 36/102 reads (35%) | catalogued as COSV100571783; called by muse, mutect2, varscan2
- PLPPR5 | c.678A>G p.L226= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1019608060, COSV99587707; called by muse, mutect2, varscan2
- PTGDR2 | c.540T>C p.I180= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs1255452466, COSV99920227; called by muse, mutect2, varscan2
- PTPN5 | c.1599G>A p.Q533= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100080155; called by muse, mutect2, varscan2
- PVALB | c.93C>T p.F31= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99342888; called by muse, mutect2, varscan2
- RAET1G | c.687C>T p.L229= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs1409186743, COSV100951684; called by muse, mutect2, varscan2
- RMC1 | c.711A>T p.T237= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV99340335; called by muse, mutect2, varscan2
- RMC1 | c.1122A>T p.G374= | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99340338; called by muse, mutect2, varscan2
- RNASE12 | c.330C>T p.L110= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs1050808874, COSV100250588; called by muse, mutect2, varscan2
- SH3GL2 | c.321T>C p.D107= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs1225944155, COSV101014668; called by muse, mutect2, varscan2
- SLAMF6 | c.102G>A p.L34= | Silent (SNP) | VAF 75/219 reads (34%) | catalogued as COSV100924918; called by muse, mutect2, varscan2
- SLAMF8 | c.120C>A p.P40= | Silent (SNP) | VAF 72/219 reads (33%) | catalogued as COSV99223050; called by muse, mutect2, varscan2
- SLC22A9 | c.1506T>C p.Y502= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as COSV99655265; called by muse, mutect2, varscan2
- SLC39A14 | c.1024C>T p.L342= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV99249919; called by muse, mutect2, varscan2
- SOCS5 | c.102C>T p.S34= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as COSV100125401; called by muse, mutect2, varscan2
- SPTA1 | c.2844C>G p.L948= | Silent (SNP) | VAF 55/204 reads (27%) | catalogued as rs762417866, COSV100934809, COSV63748650; called by muse, mutect2, varscan2
- SUPV3L1 | c.372C>T p.F124= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV100669810; called by muse, mutect2, varscan2
- SYNE1 | c.12390G>A p.Q4130= (on ENST00000367255 / NM_182961.4; = p.Q4059= on NM_033071.3) | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99573595; called by muse, mutect2, varscan2
- TANC2 | c.5547A>C p.I1849= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV101267628; called by muse, mutect2, varscan2
- TANGO6 | c.2937C>T p.A979= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99936733; called by muse, mutect2
- TBX1 | c.852C>G p.L284= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100226562; called by muse, mutect2, varscan2
- TLL2 | c.2787C>T p.Y929= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs973244513, COSV100780368, COSV100780407; called by muse, mutect2, varscan2
- TRBV29-1 | c.249C>A p.I83= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs777330589; called by muse, mutect2, varscan2
- TTN | c.44751A>T p.P14917= (on ENST00000591111; = p.P7493= on NM_003319.4) | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as COSV100623145; called by muse, mutect2, varscan2
- TTN | c.33420T>C p.P11140= (on ENST00000591111; = p.P10213= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV59950594; called by muse, mutect2, varscan2
- TTN | c.21909A>C p.A7303= (on ENST00000591111; = p.A6376= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as COSV100623146; called by muse, mutect2, varscan2
- TTYH1 | c.906C>G p.L302= | Silent (SNP) | VAF 95/204 reads (47%) | catalogued as COSV100002301; called by muse, mutect2, varscan2
- VASH2 | c.759C>T p.P253= (on ENST00000517399 / NM_001301056.2; = p.P209= on NM_024749.5) | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99663649; called by muse, mutect2, varscan2
- ZFHX3 | c.7188A>G p.P2396= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as COSV99213984; called by muse, mutect2, varscan2
- ZNF394 | c.1305C>T p.T435= | Silent (SNP) | VAF 41/140 reads (29%) | catalogued as rs745778788, COSV100529930; called by muse, mutect2, varscan2
- ZNF804A | c.513T>A p.I171= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100169333; called by muse, mutect2, varscan2
- ZSCAN1 | c.963G>C p.P321= | Silent (SNP) | VAF 30/53 reads (57%) | catalogued as COSV99991887; called by muse, mutect2, varscan2
- ZSWIM8 | c.3912T>C p.Y1304= (on ENST00000605216 / NM_001242487.2; = p.Y1309= on NM_015037.3) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs768605949, COSV100014240; called by muse, mutect2, varscan2
- FAM27E5 | n.396G>A | RNA (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- PRND | chr20:4732420 T>C | 3'Flank (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- RPP38 | chr10:15096567 C>T | 5'Flank (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.10361-5075C>A | Intron (SNP) | VAF 38/123 reads (31%) | catalogued as COSV100623148; called by muse, mutect2, varscan2
- TTN | c.10360+1362del | Intron (DEL) | VAF 29/106 reads (27%) | catalogued as COSV60229682; called by mutect2, pindel, varscan2
- TUBA3E | c.*2G>A | 3'UTR (SNP) | VAF 20/88 reads (23%) | catalogued as COSV99919883; called by muse, mutect2, varscan2
- USH1C | c.1285-7421C>A | Intron (SNP) | VAF 31/58 reads (53%) | catalogued as COSV99139585, COSV99140883; called by muse, mutect2, varscan2
- VNN3 | c.*602C>T | 3'UTR (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99258121, COSV99258503; called by muse, mutect2, varscan2
